Somatic mutation profile of tumor specimen TCGA-AG-A01W-01A (aliquot TCGA-AG-A01W-01A-21W-A096-10) from TCGA case TCGA-AG-A01W, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 67.7 years (24,745 days).
Specimen TCGA-AG-A01W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a8a4609-9787-404e-ac58-3ef92f3043a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A01W-11A (Solid Tissue Normal), aliquot TCGA-AG-A01W-11A-11W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d16a4417-70b9-475c-890a-104080a40fbb

The open-access MAF lists 152 somatic variants for this specimen: 113 protein-altering or splice-affecting, 36 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 36, Frame Shift Del 7, Nonsense Mutation 5, RNA 2, Splice Site 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 38/162 reads (23%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DHODH | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs201947120, CM100131; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 136/238 reads (57%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MUTYH | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 32/123 reads (26%) | catalogued as rs138775799, CM030378; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 147/248 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.141C>G p.S47R | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99367726; called by muse, mutect2, varscan2
- ACSBG2 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as rs372123644; called by muse, mutect2, varscan2
- ADAM11 | c.1618-2A>G p.X540_splice | Splice Site (SNP) | VAF 13/170 reads (8%) | catalogued as rs1162350399, COSV99567189; called by muse, mutect2
- ADGRL3 | c.1715G>A p.R572Q (on ENST00000506720 / NM_001322402.2; = p.R504Q on NM_015236.6) | Missense Mutation (SNP) | VAF 106/350 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as rs756595801, COSV72230132; called by muse, varscan2
- AHNAK2 | c.2944G>A p.G982R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV60912119; called by muse, mutect2, varscan2
- AKR1B15 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 111/345 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV71151463, COSV71151951; called by muse, mutect2, varscan2
- ANKDD1A | c.1164C>T p.D388= | Splice Region (SNP) | VAF 109/151 reads (72%) | catalogued as COSV63087256; called by muse, mutect2, varscan2
- ANKRD30A | c.3053T>C p.V1018A (on ENST00000611781; = p.V962A on NM_052997.2) | Missense Mutation (SNP) | VAF 23/254 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.672); catalogued as COSV64614621; called by muse, mutect2, varscan2
- ANKRD44 | c.491C>A p.A164E | Missense Mutation (SNP) | VAF 54/318 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56552419; called by muse, varscan2
- APC | c.4469del p.H1490Lfs*17 | Frame Shift Del (DEL) | VAF 30/123 reads (24%) | catalogued as COSV57334262, COSV99072989; called by mutect2, pindel, varscan2
- ATP10A | c.2876C>A p.P959Q | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.877); catalogued as rs571308575, COSV100790981; called by muse, mutect2
- BMX | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 65/404 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.022); catalogued as rs763057245, COSV59590895; called by muse, mutect2, varscan2
- BNC1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 113/238 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61757496; called by muse, mutect2, varscan2
- BRINP3 | c.1519C>T p.R507* | Nonsense Mutation (SNP) | VAF 75/461 reads (16%) | catalogued as COSV100818702, COSV66515003; called by muse, mutect2, varscan2
- BSN | c.10408C>T p.R3470W | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751110961, COSV56513313; called by muse, mutect2, varscan2
- CACNG7 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs755028200, COSV99711874; called by muse, mutect2, varscan2
- CBLB | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 103/518 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99912875; called by muse, mutect2, varscan2
- CCDC178 | c.2312T>C p.L771S (on ENST00000383096 / NM_001105528.3; = p.L733S on NM_198995.3) | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55767620; called by muse, mutect2, varscan2
- CCDC70 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs776258427, COSV54429901; called by muse, mutect2, varscan2
- CHD6 | c.2393G>A p.G798D | Missense Mutation (SNP) | VAF 328/695 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.659); catalogued as COSV100497881; called by muse, mutect2, varscan2
- CHST15 | c.1315G>A p.V439I | Missense Mutation (SNP) | VAF 89/189 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs777679104, COSV60561255; called by muse, mutect2, varscan2
- CORIN | c.1324C>G p.L442V | Missense Mutation (SNP) | VAF 91/351 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV99903103; called by muse, mutect2, varscan2
- CSK | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1312749029, COSV99583488; called by muse, mutect2, varscan2
- CSMD1 | c.9221C>T p.T3074I (on ENST00000520002; = p.T3073I on NM_033225.6) | Missense Mutation (SNP) | VAF 141/326 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs375759183; called by muse, varscan2
- CSMD3 | c.9901A>C p.K3301Q (on ENST00000297405 / NM_001363185.1; = p.K3132Q on NM_052900.3) | Missense Mutation (SNP) | VAF 69/435 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV99827554; called by muse, mutect2, varscan2
- CSMD3 | c.7550del p.G2517Dfs*22 (on ENST00000297405 / NM_001363185.1; = p.G2413Dfs*22 on NM_052900.3) | Frame Shift Del (DEL) | VAF 53/333 reads (16%) | catalogued as COSV52296351, COSV99830648; called by mutect2, pindel, varscan2
- DCSTAMP | c.674T>G p.L225R | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV52577079; called by muse, mutect2, varscan2
- DENND2D | c.743T>C p.F248S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100718551; called by muse, mutect2, varscan2
- DERL2 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 115/249 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV50147221; called by muse, mutect2, varscan2
- DLG2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 100/776 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.145); catalogued as COSV54643653; called by muse, varscan2
- DNAH10 | c.2885C>T p.T962M (on ENST00000409039; = p.T901M on NM_207437.3) | Missense Mutation (SNP) | VAF 164/705 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.417); catalogued as rs755255812, COSV68991116; called by muse, mutect2, varscan2
- DNM2 | c.638G>A p.G213D | Missense Mutation (SNP) | VAF 49/261 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100116894; called by muse, mutect2, varscan2
- DPP10 | c.1651C>T p.L551F | Missense Mutation (SNP) | VAF 81/697 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV59697340; called by muse, mutect2, varscan2
- DYNC2H1 | c.6170A>C p.D2057A | Missense Mutation (SNP) | VAF 96/651 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100517802; called by muse, mutect2, varscan2
- ERLEC1 | c.745T>G p.Y249D | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51751149; called by muse, mutect2, varscan2
- ERMARD | c.565T>A p.L189I | Missense Mutation (SNP) | VAF 125/560 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100824759; called by muse, mutect2, varscan2
- ERMARD | c.1050G>C p.E350D | Missense Mutation (SNP) | VAF 73/409 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100824537; called by muse, mutect2, varscan2
- ETNK2 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as rs759671962, COSV65820568; called by muse, mutect2, varscan2
- F13B | c.1909G>T p.D637Y | Missense Mutation (SNP) | VAF 186/361 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV66373120; called by muse, mutect2, varscan2
- F8 | c.4375A>C p.K1459Q | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as COSV100811308; called by mutect2, varscan2
- FAM104B | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.992); catalogued as rs926507346, COSV100145974; called by muse, mutect2, varscan2
- FAM50B | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172044388, COSV66654670; called by muse, mutect2, varscan2
- FIGN | c.415C>A p.L139I | Missense Mutation (SNP) | VAF 128/372 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100291727; called by muse, mutect2, varscan2
- GALNTL6 | c.1347G>T p.E449D | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV72490327; called by muse, mutect2, varscan2
- GFRA3 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.476); catalogued as rs1183313151, COSV51228252; called by muse, mutect2, varscan2
- GPRC5C | c.824C>A p.A275D (on ENST00000652232; = p.A230D on NM_018653.4) | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV100702823; called by muse, mutect2, varscan2
- GRIK2 | c.2242C>T p.R748W | Missense Mutation (SNP) | VAF 91/198 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759453868, COSV59726330; called by muse, mutect2, varscan2
- HMGB3 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 33/170 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as COSV57485779; called by muse, mutect2, varscan2
- IGFN1 | c.2223G>T p.E741D (on ENST00000295591 / NM_001367841.1; = p.E3198D on NM_001164586.2) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV55170006, COSV99812975; called by muse, mutect2, varscan2
- IREB2 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 29/511 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs753403583, COSV51922325; called by muse, mutect2
- ITGA10 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 42/241 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs587701227, COSV65198194; called by muse, mutect2, varscan2
- ITPR2 | c.5540G>C p.G1847A | Missense Mutation (SNP) | VAF 230/399 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV101189859; called by muse, mutect2, varscan2
- KCNQ5 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 32/409 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100571506; called by muse, mutect2
- KCNT2 | c.457T>G p.S153A | Missense Mutation (SNP) | VAF 42/335 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99652093; called by muse, mutect2, varscan2
- KIAA1841 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 93/388 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as COSV54374040; called by muse, mutect2, varscan2
- MAGED2 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs1200366548, COSV54497477; called by muse, mutect2, varscan2
- MDGA2 | c.1951T>G p.L651V (on ENST00000399232 / NM_001113498.2; = p.L353V on NM_182830.4) | Missense Mutation (SNP) | VAF 84/275 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.106); catalogued as COSV62085540; called by muse, mutect2, varscan2
- MEIOC | c.2059G>T p.G687W | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1354912393, COSV100740168; called by muse, mutect2, varscan2
- MIS18BP1 | c.2370A>T p.K790N | Missense Mutation (SNP) | VAF 79/357 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV60369994; called by muse, mutect2, varscan2
- MTFR1L | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV65352701; called by muse, mutect2, varscan2
- MUC17 | c.11241G>T p.M3747I | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.035); catalogued as rs1200214531, COSV60283421; called by muse, mutect2, varscan2
- MYO1H | c.645G>T p.E215D | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60444429; called by muse, mutect2
- MYOM2 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs771989991, COSV100036928; called by muse, mutect2, varscan2
- NCAM1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 156/458 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV57513846; called by muse, mutect2, varscan2
- NEB | c.7327A>C p.S2443R | Missense Mutation (SNP) | VAF 103/725 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51052075; called by muse, mutect2, varscan2
- OR2M5 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 27/597 reads (5%) | catalogued as COSV63545545, COSV63546003; called by muse, mutect2
- PCDHB7 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.258); catalogued as rs369077920; called by muse, mutect2, varscan2
- PCID2 | c.666T>G p.F222L | Missense Mutation (SNP) | VAF 202/475 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.728); catalogued as COSV55813354; called by muse, mutect2, varscan2
- PDLIM2 | c.978C>G p.F326L (on ENST00000397760; = p.F576L on NM_021630.6) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56132264; called by muse, mutect2, varscan2
- PEG3 | c.3440C>G p.T1147S | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.94); catalogued as COSV55629780; called by muse, mutect2, varscan2
- PGAP6 | c.1844G>T p.G615V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV51738663; called by muse, mutect2
- PLCH1 | c.3523A>T p.S1175C (on ENST00000340059 / NM_001130960.2; = p.S1167C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV100395899; called by muse, mutect2, varscan2
- PLXDC2 | c.1539A>C p.E513D | Missense Mutation (SNP) | VAF 70/496 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101022822, COSV65902507; called by muse, mutect2, varscan2
- POLE | c.6037G>A p.D2013N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57677633; called by muse, mutect2, varscan2
- PRKG2 | c.1290_1299del p.S431* | Frame Shift Del (DEL) | VAF 23/191 reads (12%) | catalogued as COSV52322174; called by mutect2, pindel, varscan2
- PSME4 | c.4985T>G p.L1662R | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101122310; called by muse, mutect2
- PTPRC | c.149T>C p.L50S | Missense Mutation (SNP) | VAF 39/625 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.062); catalogued as COSV100722226; called by muse, mutect2
- RPL28 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV59804626; called by muse, mutect2, varscan2
- RYR2 | c.10058T>C p.L3353P | Missense Mutation (SNP) | VAF 135/361 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100768618; called by muse, mutect2, varscan2
- SCN9A | c.4207G>T p.A1403S (on ENST00000303354; = p.A1392S on NM_002977.3) | Missense Mutation (SNP) | VAF 55/416 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100311766, COSV57619799; called by muse, mutect2, varscan2
- SERPINA3 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs375245228; called by muse, mutect2, varscan2
- SIGLEC7 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.302); catalogued as rs368230574, COSV58315269; called by muse, mutect2, varscan2
- SLC1A6 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.135); catalogued as rs200538770; called by muse, mutect2, varscan2
- SLC4A2 | c.459+1G>C p.X153_splice | Splice Site (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100054993; called by muse, varscan2
- SLC5A4 | c.1220T>C p.I407T | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs748146452, COSV56669491; called by muse, varscan2
- SMAD2 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 130/332 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100053439, COSV50992856; called by muse, varscan2
- STRADB | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.238); catalogued as COSV52043186; called by muse, mutect2, varscan2
- SYT6 | c.962G>A p.R321H (on ENST00000610222 / NM_001366225.1; = p.R236H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs549305784, COSV65773471, COSV65774250; called by muse, mutect2, varscan2
- TEX44 | c.1169C>A p.A390D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.965); catalogued as COSV58354837; called by muse, mutect2, varscan2
- TLE4 | c.50C>A p.P17Q | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54629756, COSV54641686; called by muse, mutect2, varscan2
- TMEM47 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 34/664 reads (5%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.49); catalogued as rs779449154, COSV52064715; called by muse, mutect2
- USH1G | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV58881317; called by muse, mutect2
- VAT1L | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56829986; called by muse, mutect2, varscan2
- VIRMA | c.4763G>T p.G1588V | Missense Mutation (SNP) | VAF 139/671 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52583665; called by muse, mutect2, varscan2
- VSIG1 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 15/378 reads (4%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.009); catalogued as COSV99480178; called by muse, mutect2
- XKR3 | c.1292A>G p.K431R | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as COSV100509156; called by muse, mutect2, varscan2
- ZC3H7B | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs774780753, COSV100687104; called by muse, mutect2, varscan2
- ZNF484 | c.1130T>A p.I377N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.316); catalogued as COSV100214501, COSV60256072; called by muse, mutect2, varscan2
- ZNF532 | c.979C>A p.P327T | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV60172475; called by muse, mutect2, varscan2
- ZNF829 | c.755G>T p.C252F | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV66986054, COSV66986144; called by muse, mutect2, varscan2
- ZNF835 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as COSV73379341, COSV73379433; called by muse, mutect2, varscan2
- BCL9 | c.3018_3021del p.S1007Lfs*2 | Frame Shift Del (DEL) | VAF 73/460 reads (16%) | called by mutect2, pindel, varscan2
- CHD2 | c.2702C>T p.A901V | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGKV1-27 | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.176); called by muse, mutect2
- NBPF15 | c.1871C>T p.S624L | Missense Mutation (SNP) | VAF 476/925 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC25A26 | c.248_249del p.S83Ffs*27 | Frame Shift Del (DEL) | VAF 139/757 reads (18%) | called by mutect2, pindel, varscan2
- TEP1 | c.7513del p.W2505Gfs*41 | Frame Shift Del (DEL) | VAF 111/793 reads (14%) | called by mutect2, pindel, varscan2
- TUT7 | c.2479_2480del p.L827Kfs*18 | Frame Shift Del (DEL) | VAF 28/107 reads (26%) | called by pindel, varscan2
- ADGRF5 | c.1320G>A p.S440= | Silent (SNP) | VAF 40/748 reads (5%) | catalogued as rs774615419, COSV51933142; called by muse, mutect2
- ADGRL3 | c.1920T>C p.A640= (on ENST00000506720 / NM_001322402.2; = p.A572= on NM_015236.6) | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV63368339; called by muse, mutect2, varscan2
- ADGRV1 | c.10602G>A p.S3534= | Silent (SNP) | VAF 183/641 reads (29%) | catalogued as rs1214460002, COSV67982637; called by muse, mutect2, varscan2
- AGK | c.630A>G p.R210= | Silent (SNP) | VAF 58/512 reads (11%) | catalogued as COSV62594161; called by muse, varscan2
- CACNA1A | c.3057G>T p.G1019= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV64194509; called by muse, mutect2, varscan2
- CASS4 | c.285G>A p.E95= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV64385886; called by muse, mutect2, varscan2
- CBARP | c.519C>T p.Y173= (on ENST00000382477; = p.Y153= on NM_152769.3) | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV53068451; called by muse, mutect2, varscan2
- CD163 | c.2403C>T p.H801= | Silent (SNP) | VAF 11/183 reads (6%) | catalogued as rs977803294, COSV63131083, COSV63135337; called by muse, mutect2
- DMBT1 | c.7572C>T p.V2524= (on ENST00000338354 / NM_001377530.1; = p.V1767= on NM_004406.3) | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV57534536; called by muse, mutect2, varscan2
- EPDR1 | c.456G>A p.S152= | Silent (SNP) | VAF 70/175 reads (40%) | catalogued as rs200760284; called by muse, mutect2, varscan2
- EYA4 | c.1071C>A p.S357= (on ENST00000531901 / NM_001301013.1; = p.S351= on NM_004100.5) | Silent (SNP) | VAF 18/516 reads (3%) | catalogued as COSV100765346; called by muse, mutect2
- KRT75 | c.450C>T p.R150= | Silent (SNP) | VAF 58/236 reads (25%) | catalogued as rs138137930, COSV52870803; called by muse, mutect2, varscan2
- MAGEA4 | c.642C>T p.G214= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as rs376198310, COSV52340253, COSV52340877; called by muse, mutect2, varscan2
- MAP2 | c.4032A>G p.K1344= | Silent (SNP) | VAF 17/198 reads (9%) | catalogued as COSV99558407; called by muse, mutect2
- MMP17 | c.594C>T p.Y198= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs766543538, COSV62178872; called by muse, varscan2
- NT5C1B | c.1680C>T p.D560= (on ENST00000359846 / NM_001199086.2; = p.D500= on NM_033253.4) | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs772615000, COSV100409831; called by muse, mutect2, varscan2
- OSBPL8 | c.99C>T p.D33= | Silent (SNP) | VAF 46/541 reads (9%) | catalogued as rs202014462, COSV53880563; called by muse, mutect2
- PCDH9 | c.930G>A p.G310= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV60540377; called by muse, mutect2, varscan2
- PCDHA4 | c.468C>T p.G156= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100793215; called by muse, mutect2, varscan2
- PCLO | c.7905A>C p.S2635= | Silent (SNP) | VAF 41/226 reads (18%) | catalogued as COSV61626077, COSV61639040; called by muse, mutect2, varscan2
- RALGDS | c.894A>C p.T298= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV64426503; called by muse, mutect2, varscan2
- RBM12 | c.873G>A p.Q291= | Silent (SNP) | VAF 14/193 reads (7%) | catalogued as COSV100467137; called by muse, mutect2
- RHOBTB1 | c.1764G>A p.T588= | Silent (SNP) | VAF 58/203 reads (29%) | catalogued as rs556718498, COSV61958179; called by muse, mutect2, varscan2
- ROBO2 | c.3340T>C p.L1114= | Silent (SNP) | VAF 45/222 reads (20%) | catalogued as COSV59905164; called by muse, mutect2, varscan2
- RPS6KA2 | c.1686C>T p.R562= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as COSV55818608; called by muse, mutect2, varscan2
- SCN10A | c.3828C>T p.G1276= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as rs375572917; called by muse, mutect2, varscan2
- SIM1 | c.1320G>A p.S440= | Silent (SNP) | VAF 58/129 reads (45%) | catalogued as rs1164025324, COSV53490653, COSV99492722; called by muse, mutect2, varscan2
- SYNE1 | c.9978A>G p.L3326= (on ENST00000367255 / NM_182961.4; = p.L3333= on NM_033071.3) | Silent (SNP) | VAF 35/237 reads (15%) | catalogued as COSV54948618; called by muse, mutect2, varscan2
- TAF1L | c.9C>T p.P3= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs938277242, COSV54260176; called by muse, mutect2, varscan2
- TTN | c.52020G>A p.A17340= (on ENST00000591111; = p.A9916= on NM_003319.4) | Silent (SNP) | VAF 56/161 reads (35%) | catalogued as rs370998052; ClinVar: benign / uncertain significance / likely benign; called by muse, mutect2, varscan2
- UTP14A | c.1896C>T p.G632= | Silent (SNP) | VAF 49/328 reads (15%) | catalogued as COSV64086575; called by muse, mutect2, varscan2
- WDR75 | c.175C>T p.L59= | Silent (SNP) | VAF 59/416 reads (14%) | catalogued as COSV59105177; called by muse, mutect2, varscan2
- ZDBF2 | c.156G>T p.L52= | Silent (SNP) | VAF 98/487 reads (20%) | catalogued as COSV65623898; called by muse, mutect2, varscan2
- ZFHX4 | c.7110G>A p.T2370= | Silent (SNP) | VAF 24/215 reads (11%) | catalogued as COSV50534522, COSV99254900; called by muse, mutect2
- ZNF41 | c.891G>A p.K297= | Silent (SNP) | VAF 124/262 reads (47%) | catalogued as COSV57441948; called by muse, mutect2, varscan2
- ZNF804B | c.1884T>C p.P628= | Silent (SNP) | VAF 63/446 reads (14%) | catalogued as COSV60822950; called by muse, mutect2, varscan2
- NEBL | c.164+25996C>T | Intron (SNP) | VAF 102/648 reads (16%) | catalogued as COSV65798224; called by muse, mutect2, varscan2
- SPATA8 | n.778A>C | RNA (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100138900; called by muse, mutect2, varscan2
- SSPOP | n.1239C>T | RNA (SNP) | VAF 31/88 reads (35%) | catalogued as COSV50487052; called by muse, mutect2, varscan2
